TCGA case TCGA-27-1834 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7340f325-579f-4b90-96aa-3a7b362129ca

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 1,233 days (3.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 56.3 years (20,568 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: -5 days; Days to treatment end: 1,233 days (3.4 years); Treatment dose: 7,302 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 168 days; Number of cycles: 5; Treatment dose: 320 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 168 days; Number of cycles: 5; Treatment dose: 6,250 mg.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 64 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 352 days; Days to treatment end: 540 days (1.5 years); Number of cycles: 6; Treatment dose: 1,200 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Treatment intent type: Adjuvant; Days to treatment start: 352 days; Days to treatment end: 540 days (1.5 years); Number of cycles: 6; Treatment dose: 1,248 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 352 days; Days to treatment end: 662 days (1.8 years); Treatment dose: 35,000 mg; Treatment outcome: Treatment Ongoing; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 57.2 years (20,903 days); Days to diagnosis: 335 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 335 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 335 days.
- Days to follow up: 1,008 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,233 days (3.4 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-27-1834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-27-1834-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 10.
  Slide TCGA-27-1834-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 100.
- Sample TCGA-27-1834-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-27-1834-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 2, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 5: Pharmaceutical therapy drug name: Temozolomoide.
- Drug treatment 6, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,233 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,233 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 335 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-27-1834-01A-01D-0591-01): tumor purity 0.74, ploidy 1.91, whole-genome doublings 0.
